Somatic mutation profile of tumor specimen TCGA-D1-A17S-01A (aliquot TCGA-D1-A17S-01A-11D-A12J-09) from TCGA case TCGA-D1-A17S, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 59.7 years (21,794 days).
Specimen TCGA-D1-A17S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2ede5a5-e3c5-404f-988a-28b3e8e98629.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17S-10A (Blood Derived Normal), aliquot TCGA-D1-A17S-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3a1237d-fe26-497a-a7ef-eef9386d7e83

The open-access MAF lists 52 somatic variants for this specimen: 42 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 36, Silent 10, Splice Site 2, Frame Shift Ins 2, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 56/131 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 120/241 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP1S1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 5/139 reads (4%) | catalogued as COSV61760429; called by muse, mutect2
- BTN3A3 | c.1433C>T p.T478I | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV55073889; called by muse, mutect2, varscan2
- C1QTNF4 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV56782965; called by muse, mutect2, varscan2
- CACNG2 | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 93/201 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55641282; called by muse, mutect2, varscan2
- CELSR2 | c.7492G>A p.V2498M | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs144041571; called by muse, mutect2, varscan2
- CMIP | c.356T>A p.L119Q (on ENST00000537098 / NM_198390.2; = p.L25Q on NM_030629.3) | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV73345363; called by muse, mutect2, varscan2
- CTCF | c.1094A>C p.K365T | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50475306, COSV50509468; called by muse, mutect2, varscan2
- DYRK4 | c.864G>T p.W288C | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50545244; called by muse, mutect2, varscan2
- FAM71C | c.615+1G>T p.X205_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as rs1172344902, COSV60944485; called by muse, mutect2
- FNDC3B | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs755249189, COSV61043413; called by muse, mutect2, varscan2
- GARS1 | c.1754T>C p.M585T | Missense Mutation (SNP) | VAF 213/474 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs374378925; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLRA3 | c.899G>A p.S300N | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as rs773481118, COSV56870557; called by muse, mutect2, varscan2
- GMPS | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs557093697, COSV55812121; called by muse, mutect2, varscan2
- GPR19 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs566179231, COSV60124761; called by muse, mutect2, varscan2
- IFT122 | c.1861A>T p.M621L (on ENST00000348417 / NM_052989.3; = p.M562L on NM_018262.4) | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.651); catalogued as COSV56208510; called by muse, mutect2
- IL23R | c.119C>A p.T40K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV61376396; called by muse, mutect2, varscan2
- LARGE1 | c.2073G>A p.Q691= | Splice Region (SNP) | VAF 44/117 reads (38%) | catalogued as COSV61668755, COSV61672583; called by muse, mutect2, varscan2
- LRP1B | c.9346C>T p.L3116F | Missense Mutation (SNP) | VAF 199/500 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs748618648, COSV67276599; called by muse, mutect2, varscan2
- LUZP2 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV61219148; called by muse, mutect2, varscan2
- MAGEE1 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV63912170; called by muse, mutect2, varscan2
- MAP7D3 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 158/406 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs371634445, COSV60170410; called by muse, mutect2, varscan2
- MYO16 | c.3029G>A p.R1010Q | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs200881854, COSV100695006, COSV62762322; called by muse, mutect2, varscan2
- NTM | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.576); catalogued as rs1289145335, COSV100868674, COSV66178113; called by muse, mutect2, varscan2
- NXPH4 | c.724C>A p.R242S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61075408; called by muse, mutect2
- OR1K1 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as rs1317039499, COSV52957349; called by muse, mutect2, varscan2
- PAPOLA | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 191/475 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs768115714, COSV53485613; called by muse, mutect2, varscan2
- PLS1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 133/258 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs1328432317, COSV61835573; called by muse, mutect2, varscan2
- POU6F2 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 154/361 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); catalogued as COSV68873327, COSV68882851; called by muse, mutect2, varscan2
- PPP1R3A | c.1933G>T p.D645Y | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1216662506, COSV52884960; called by muse, mutect2
- PRKAA1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1433191043, COSV57185721; called by muse, mutect2, varscan2
- PTPRC | c.2276G>T p.R759M | Missense Mutation (SNP) | VAF 179/428 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61420770; called by muse, mutect2, varscan2
- SHANK3 | c.3469C>T p.R1157W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs765479159, COSV53191409; called by muse, mutect2, varscan2
- SHC1 | c.1085G>T p.G362V (on ENST00000368445 / NM_183001.5; = p.G252V on NM_003029.5) | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs746647299, COSV63534697; called by muse, mutect2, varscan2
- SMG5 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.902); catalogued as rs1016477977, COSV62433990; called by muse, mutect2, varscan2
- SPIN4 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs782121484, COSV58738664; called by muse, mutect2
- TENM3 | c.6703C>T p.R2235C | Missense Mutation (SNP) | VAF 87/194 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101305450, COSV69299638; called by muse, mutect2, varscan2
- UPF3B | c.1102C>T p.R368W (on ENST00000276201 / NM_080632.3; = p.R355W on NM_023010.3) | Missense Mutation (SNP) | VAF 195/481 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.858); catalogued as rs374676402, COSV52230481; called by muse, mutect2, varscan2
- ATP6V1C2 | c.732-3_749del p.X244_splice | Splice Site (DEL) | VAF 110/382 reads (29%) | called by mutect2, pindel, varscan2
- PTEN | c.585_586dup p.H196Lfs*4 | Frame Shift Ins (INS) | VAF 231/347 reads (67%) | called by mutect2, pindel, varscan2
- ZBED8 | c.1478dup p.N493Kfs*2 | Frame Shift Ins (INS) | VAF 63/148 reads (43%) | called by mutect2, pindel, varscan2
- C3 | c.1683C>T p.G561= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV55581695; called by muse, mutect2, varscan2
- COL5A3 | c.4713G>A p.S1571= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV53419603; called by muse, mutect2, varscan2
- DGCR8 | c.2133G>A p.S711= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as rs1457555223, COSV52815073; called by muse, mutect2
- DYNC2H1 | c.7149G>A p.T2383= | Silent (SNP) | VAF 85/209 reads (41%) | catalogued as rs553516014, COSV62107229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INTS14 | c.201G>A p.T67= | Silent (SNP) | VAF 78/172 reads (45%) | catalogued as rs374731569; called by muse, mutect2, varscan2
- LRP2 | c.10512C>T p.G3504= | Silent (SNP) | VAF 165/326 reads (51%) | catalogued as rs757173572, COSV55575399; called by muse, mutect2
- MAGEA10 | c.198A>T p.L66= | Silent (SNP) | VAF 133/303 reads (44%) | catalogued as COSV54886039; called by muse, mutect2, varscan2
- NOTCH1 | c.453C>T p.N151= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs368733465; called by muse, mutect2, varscan2
- SLC25A14 | c.951C>T p.Y317= | Silent (SNP) | VAF 30/480 reads (6%) | catalogued as rs1472208939, COSV54418228; called by muse, mutect2
- ZIM2 | c.837G>A p.P279= | Silent (SNP) | VAF 116/283 reads (41%) | catalogued as rs191866455, COSV55639172; called by muse, mutect2, varscan2
